CPTAC case C3N-01025 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bbf0c378-fb77-4768-be2b-da741ded8cab

Demographics
Sex at birth: male; Race: asian; Year of birth: 1964; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 52.9 years (19,325 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 7 days; Days to last follow up: 7 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10 cm (a second GDC size field records 6 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 15; Margin status: Uninvolved.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 7.

Other clinical attributes
- Weight: 63 kg; Height: 168 cm; BMI: 22.32.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 1.5; Cigarettes per day: 1; Tobacco smoking onset year: 1986; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 36.

Biospecimens (14 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Samples C3N-01025-01, C3N-01025-02 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-01025-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 300 mg.
- Sample C3N-01025-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 300 mg; Time between clamping and freezing: 23 minutes; Time between excision and freezing: 8 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01025-24: Section location: Right lung, not otherwise specified; Percent tumor nuclei: 75; Percent necrosis: 10.
- Sample C3N-01025-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 200 mg; Time between clamping and freezing: 24 minutes; Time between excision and freezing: 9 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-01025-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 200 mg.
- Samples C3N-01025-31, C3N-01025-32, C3N-01025-72, C3N-01025-73, C3N-01025-74, C3N-01025-75, C3N-01025-76 (7 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01025-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 7 days; Method of sample procurement: Blood Draw.
